Somatic mutation profile of tumor specimen TCGA-HE-A5NF-01A (aliquot TCGA-HE-A5NF-01A-11D-A26P-10) from TCGA case TCGA-HE-A5NF, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-HE-A5NF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 791e497a-9484-4041-adb4-305912c6cd98.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HE-A5NF-10A (Blood Derived Normal), aliquot TCGA-HE-A5NF-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/59ae0850-643f-4cf6-9003-03442eb5f1d3

The open-access MAF lists 76 somatic variants for this specimen: 56 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 12, Frame Shift Del 6, Intron 4, 3'UTR 2, Splice Site 2, Nonsense Mutation 2, Splice Region 1, Translation Start Site 1, 5'Flank 1, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.3793G>T p.A1265S | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV52198759; called by muse, varscan2
- ADAM19 | c.2580G>T p.K860N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV57427249; called by muse, mutect2, varscan2
- ADH1B | c.1101A>G p.K367= | Splice Region (SNP) | VAF 11/83 reads (13%) | catalogued as COSV59295898; called by muse, mutect2, varscan2
- AMOTL1 | c.1035G>T p.M345I | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV54414943; called by muse, mutect2, varscan2
- ATXN3 | c.571C>G p.L191V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.829); catalogued as COSV61494568; called by muse, mutect2, varscan2
- CA13 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58797468; called by muse, mutect2, varscan2
- CDH24 | c.415A>T p.K139* | Nonsense Mutation (SNP) | VAF 20/127 reads (16%) | catalogued as COSV52975073; called by muse, mutect2, varscan2
- CFAP47 | c.9490C>T p.R3164C | Missense Mutation (SNP) | VAF 54/194 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs373240572, COSV66216964; called by muse, mutect2, varscan2
- CYP11A1 | c.419T>A p.L140Q | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as COSV51431514; called by muse, mutect2, varscan2
- DCHS1 | c.7102G>C p.D2368H | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55033840; called by muse, mutect2, varscan2
- DUSP26 | c.161C>A p.T54K | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.031); catalogued as COSV56361161; called by muse, mutect2, varscan2
- ERMN | c.600A>T p.E200D | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV68075149; called by muse, mutect2, varscan2
- HPD | c.893A>C p.Q298P | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.647); catalogued as rs201305943, COSV56641612; called by muse, mutect2, varscan2
- KANK4 | c.1514G>A p.G505D | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV62986152; called by muse, mutect2, varscan2
- KCNG1 | c.782G>A p.C261Y | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV65368764; called by muse, mutect2, varscan2
- KIAA0753 | c.970C>G p.R324G | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs746068882, COSV104421290, COSV63817185; called by muse, mutect2, varscan2
- KPNA7 | c.896T>C p.V299A | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV59397808; called by muse, mutect2, varscan2
- LPAR1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1188890764, COSV62688188; called by muse, mutect2, varscan2
- LRP4 | c.3232A>G p.I1078V | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs1280960378, COSV66135185; called by muse, mutect2, varscan2
- LZTS2 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as COSV64651370; called by muse, mutect2, varscan2
- MCM3AP | c.4999G>A p.G1667R | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs777598152, COSV52437920, COSV99387306; called by muse, mutect2, varscan2
- MED10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/42 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV55385929; called by muse, mutect2, varscan2
- NKX2-2 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV65819374; called by muse, mutect2
- NUDT13 | c.102G>T p.K34N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61968509; called by muse, mutect2, varscan2
- NYNRIN | c.4082G>T p.G1361V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.652); catalogued as COSV66841886; called by muse, mutect2, varscan2
- OBSL1 | c.5602C>A p.H1868N | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.364); catalogued as COSV54705082; called by muse, mutect2, varscan2
- OCIAD2 | c.444C>A p.D148E | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56716488; called by muse, mutect2, varscan2
- PI4KA | c.2445G>A p.W815* | Nonsense Mutation (SNP) | VAF 26/137 reads (19%) | catalogued as COSV55408486; called by muse, mutect2, varscan2
- POM121C | c.1337C>T p.P446L (on ENST00000607367; = p.P204L on NM_001099415.3) | Missense Mutation (SNP) | VAF 60/418 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as rs1554471632, COSV57545098; called by muse, varscan2
- RMI1 | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57935881; called by muse, mutect2, varscan2
- SERINC1 | c.1293G>C p.W431C | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60101838; called by muse, mutect2, varscan2
- SHBG | c.334C>G p.H112D | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV52646587; called by muse, mutect2, varscan2
- SLC12A3 | c.1832A>C p.N611T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CD117020, CM075008, CM094406, COSV52633973; called by muse, mutect2, varscan2
- SPTAN1 | c.3548A>T p.E1183V | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.165); catalogued as COSV63986389; called by muse, mutect2, varscan2
- SRGAP3 | c.925C>A p.L309M | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV64532136; called by muse, mutect2, varscan2
- STAG1 | c.3537A>T p.R1179S | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.744); catalogued as COSV52606540; called by muse, mutect2, varscan2
- SYDE2 | c.1862T>A p.L621H | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52314968; called by muse, mutect2, varscan2
- TEP1 | c.5879C>A p.S1960Y | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV52990998, COSV53002146; called by muse, mutect2, varscan2
- TIAL1 | c.514T>G p.W172G | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV64843089; called by muse, mutect2, varscan2
- TLE3 | c.272A>T p.Q91L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV58168296; called by muse, mutect2
- TOB1 | c.645C>G p.D215E | Missense Mutation (SNP) | VAF 59/217 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV52149906, COSV52150024; called by muse, mutect2, varscan2
- TOMM40 | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV52976715; called by muse, mutect2, varscan2
- UBE2K | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV54689794; called by muse, mutect2, varscan2
- UBR3 | c.1714T>A p.F572I | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV55847478; called by muse, mutect2, varscan2
- UNC5CL | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV55109564; called by muse, mutect2, varscan2
- VWA5B2 | c.1606A>T p.T536S | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV56610999, COSV56613779; called by muse, mutect2, varscan2
- WDR11 | c.3028-1G>A p.X1010_splice | Splice Site (SNP) | VAF 15/99 reads (15%) | catalogued as COSV54787256; called by muse, mutect2
- ZNF140 | c.1199T>C p.L400P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60579385; called by muse, mutect2, varscan2
- AEBP1 | c.1510del p.D504Tfs*5 | Frame Shift Del (DEL) | VAF 23/101 reads (23%) | called by mutect2, pindel, varscan2
- ARHGEF4 | c.1598del p.K533Rfs*35 | Frame Shift Del (DEL) | VAF 45/191 reads (24%) | called by mutect2, pindel, varscan2
- CTNNA1 | c.137_138del p.G46Afs*3 | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- FAT4 | c.12941del p.N4314Mfs*83 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- MLH3 | c.154_158del p.V52Sfs*11 | Frame Shift Del (DEL) | VAF 28/164 reads (17%) | called by mutect2, pindel, varscan2
- SLC35B3 | c.781-3_797del p.X261_splice | Splice Site (DEL) | VAF 15/137 reads (11%) | called by mutect2, pindel
- TG | c.2110_2111dup p.C705Tfs*17 | Frame Shift Ins (INS) | VAF 79/469 reads (17%) | called by mutect2, pindel, varscan2
- ZW10 | c.953del p.N318Mfs*16 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | called by mutect2, pindel, varscan2
- AGRN | c.324C>A p.S108= | Silent (SNP) | VAF 34/201 reads (17%) | catalogued as COSV65068868; called by muse, mutect2, varscan2
- CNOT3 | c.468G>A p.K156= | Silent (SNP) | VAF 62/377 reads (16%) | catalogued as COSV55362073; called by muse, mutect2, varscan2
- HSPA6 | c.756G>A p.G252= | Silent (SNP) | VAF 13/131 reads (10%) | catalogued as rs760939179, COSV59060647; called by muse, mutect2, varscan2
- NTRK1 | c.2341C>T p.L781= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV62324822; called by muse, mutect2
- OTUD3 | c.942T>C p.N314= | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as COSV64295691; called by muse, mutect2, varscan2
- RPL24 | c.186A>G p.G62= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as COSV67529798; called by muse, mutect2, varscan2
- SETD4 | c.1320C>G p.T440= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV59771846; called by muse, mutect2, varscan2
- SNED1 | c.4140A>T p.R1380= | Silent (SNP) | VAF 70/187 reads (37%) | catalogued as COSV54088625; called by muse, mutect2, varscan2
- SOCS7 | c.891C>A p.T297= | Silent (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2
- SPINK13 | c.198C>T p.H66= | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as rs766312278, COSV68241359; called by muse, mutect2, varscan2
- TBC1D5 | c.6T>C p.Y2= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV53753810; called by muse, mutect2, varscan2
- TMBIM4 | c.216A>G p.L72= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV53968514; called by muse, mutect2
- ETNK2 | c.1015-39G>C | Intron (SNP) | VAF 33/150 reads (22%) | catalogued as COSV65819730; called by muse, mutect2, varscan2
- HPS6 | c.*123G>T | 3'UTR (SNP) | VAF 18/147 reads (12%) | catalogued as COSV100154993; called by muse, mutect2, varscan2
- MIR1270 | chr19:20398324 C>A | 3'Flank (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- PRRT1 | chr6:32152104 C>T | 5'Flank (SNP) | VAF 5/38 reads (13%) | catalogued as rs1044948087, COSV99278656; called by muse, mutect2, varscan2
- PTGER3 | c.*24-12884A>T | Intron (SNP) | VAF 19/134 reads (14%) | called by muse, mutect2, varscan2
- ST7L | c.205+894T>C | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- SVIL | c.-201+32082A>G | Intron (SNP) | VAF 27/78 reads (35%) | catalogued as COSV100881520; called by muse, mutect2
- ZFP2 | c.*335G>T | 3'UTR (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100797121; called by muse, mutect2, varscan2
